Somatic mutation profile of tumor specimen TCGA-BJ-A45D-01A (aliquot TCGA-BJ-A45D-01A-11D-A23U-08) from TCGA case TCGA-BJ-A45D, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.5 years (13,335 days).
Specimen TCGA-BJ-A45D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b20a9172-bd10-4c03-8f97-42c46bb0a811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45D-10A (Blood Derived Normal), aliquot TCGA-BJ-A45D-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffec3162-11ed-4439-8053-6444b8248e1a

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Del 2, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 33/146 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OPRL1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs760133694, COSV61090957; called by muse, mutect2, varscan2
- RNF34 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV63443326; called by muse, mutect2
- TG | c.6844_6847del p.L2282Ifs*61 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs774153375; called by pindel, varscan2
- ARHGEF12 | c.3523C>T p.Q1175* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- PGK1 | c.1079_1090delinsA p.V360Dfs*2 | Frame Shift Del (DEL) | VAF 16/27 reads (59%) | called by pindel, varscan2*
- SLC25A13 | c.1479C>G p.D493E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRP68 | c.1473A>G p.K491= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs761404186, COSV57161556; called by muse, mutect2, varscan2
